Somatic mutation profile of tumor specimen C3L-04766-54 (aliquot CPT0260660002) from CPTAC case C3L-04766, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 42.8 years (15,640 days).
Specimen C3L-04766-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7055160-104d-406e-bdbc-073b3616c45d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04766-51 (Buccal Cell Normal), aliquot CPT0260650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a28cb39b-cba8-4399-aa61-36e0ce0b25f9

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.4044G>C p.M1348I (on ENST00000303395 / NM_001202435.3; = p.M1337I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs794726822, CM1511245; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYLC1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61411029; called by muse, mutect2
- HUNK | c.336C>T p.S112= | Silent (SNP) | VAF 55/98 reads (56%) | called by muse, varscan2
- NPAP1 | c.285G>A p.R95= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV61510930; called by muse, varscan2
